Gene-level copy-number profile of tumor specimen TCGA-HI-7171-01A from TCGA case TCGA-HI-7171, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.9 years (20,776 days).
Specimen TCGA-HI-7171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.e1a4a905-fd47-4d90-aaeb-590ea11e0cbd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HI-7171-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3a5254a-6c80-448b-8ede-f08e88846ba0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 79; copy number 2: 7,237; copy number 3: 6,826; copy number 4: 43,116; copy number 5: 2,458; copy number 6: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HI-7171-01A-12D-2112-01): tumor purity 0.88, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,918,443–64,942,365, 2 genes: AL606517.2, AL606517.1.
- chr1:65,057,755–65,415,871, 9 genes (within-gene range 0–2): MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13.
- chr8:42,043,504–42,139,752, 4 genes: AC090571.1, AC103724.1, AC103724.2, AC103724.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
